Somatic mutation profile of tumor specimen C3L-00418-03 (aliquot CPT0006670009) from CPTAC case C3L-00418, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.8 years (20,747 days).
Specimen C3L-00418-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34758fe8-9e2a-4204-ab01-a0bb0670d0d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00418-31 (Blood Derived Normal), aliquot CPT0002730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/481fadd2-5981-42f8-96b1-871c5ab1101c

The open-access MAF lists 80 somatic variants for this specimen: 56 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Frame Shift Del 9, Intron 5, Nonsense Mutation 3, Frame Shift Ins 1, 3'UTR 1, RNA 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794726890, CD941806, CM023994, HM090060, COSV56545575, COSV56546439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRF1 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV51944859; called by muse, mutect2, varscan2
- ALPK1 | c.2683A>T p.N895Y | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.122); catalogued as COSV51589517; called by muse, mutect2, varscan2
- ARSF | c.1272del p.I424Mfs*50 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | catalogued as COSV63841335; called by mutect2, pindel
- CASP5 | c.560del p.K187Rfs*33 | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | catalogued as rs753743648; called by mutect2, pindel
- CNTN5 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 56/691 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs752165707, COSV54306589; called by muse, mutect2
- KSR1 | c.2612del p.F871Sfs*143 (on ENST00000644974 / NM_001367810.1; = p.F756Sfs*86 on NM_014238.2) | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as COSV52028721; called by mutect2, pindel, varscan2
- LACRT | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.094); catalogued as COSV99143822; called by muse, mutect2, varscan2
- NAGPA | c.1147G>C p.G383R | Missense Mutation (SNP) | VAF 83/414 reads (20%) | PolyPhen probably damaging (1); catalogued as rs764803464; called by muse, mutect2, varscan2
- PLEKHG4B | c.2896G>T p.E966* (on ENST00000283426; = p.E1322* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 40/261 reads (15%) | catalogued as COSV52044158; called by muse, mutect2, varscan2
- SLC25A29 | c.529C>G p.R177G (on ENST00000359232 / NM_001039355.3; = p.R111G on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV63650822; called by muse, mutect2, varscan2
- SLC6A16 | c.1885A>G p.M629V | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60027373; called by muse, mutect2, varscan2
- TNKS | c.1898A>C p.E633A | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as rs775388553; called by muse, varscan2
- TOP2B | c.3742G>A p.A1248T (on ENST00000264331 / NM_001330700.2; = p.A1243T on NM_001068.3) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs761832827; called by muse, mutect2, varscan2
- ZNF432 | c.876del p.N292Kfs*93 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as COSV55418185; called by mutect2, pindel, varscan2
- ZNF648 | c.1319del p.T440Sfs*52 | Frame Shift Del (DEL) | VAF 47/223 reads (21%) | catalogued as COSV60572444; called by mutect2, pindel*, varscan2
- ACAP2 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ACAP2 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ANXA3 | c.843A>T p.E281D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CAPG | c.989T>G p.I330S | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- CLCN5 | c.39del p.Q14Sfs*17 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel
- CLCNKB | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CLMN | c.2230G>T p.V744L | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.038); called by muse, mutect2
- COL3A1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.096); called by muse, mutect2
- COPS2 | c.857T>G p.L286R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYTH1 | c.700-1G>T p.X234_splice | Splice Site (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- GRINA | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, mutect2
- KANSL3 | c.1807T>A p.S603T | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCND1 | c.1005G>T p.M335I | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KLK13 | c.769T>C p.W257R | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LONRF2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LRP2 | c.4460A>G p.Q1487R | Missense Mutation (SNP) | VAF 81/416 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MELK | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP24 | c.1220A>T p.N407I | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- MMP24 | c.1553A>G p.K518R | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MRE11 | c.566T>A p.L189H | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRBP1 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 62/310 reads (20%) | called by muse, mutect2, varscan2
- PBRM1 | c.1041_1051del p.M347Ifs*6 | Frame Shift Del (DEL) | VAF 31/188 reads (16%) | called by mutect2, pindel, varscan2
- PCBP2 | c.896T>C p.I299T (on ENST00000439930 / NM_001128911.2; = p.I300T on NM_005016.6) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PLAT | c.604T>C p.F202L | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLD2 | c.2124G>A p.R708= | Splice Region (SNP) | VAF 22/200 reads (11%) | called by muse, mutect2, varscan2
- PRPF8 | c.4747C>T p.Q1583* | Nonsense Mutation (SNP) | VAF 57/386 reads (15%) | called by muse, mutect2, varscan2
- SLC26A3 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 26/367 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2
- SLITRK3 | c.2484C>A p.N828K | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SNAP91 | c.2175G>T p.L725F | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPAST | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM87A | c.947G>C p.S316T | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOMM5 | c.93del p.L32Sfs*14 | Frame Shift Del (DEL) | VAF 46/278 reads (17%) | called by mutect2, pindel, varscan2
- TPCN2 | c.2208T>A p.D736E | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRPM8 | c.1340dup p.T448Hfs*3 | Frame Shift Ins (INS) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- TTC3 | c.3925G>A p.A1309T | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.23839C>T p.P7947S (on ENST00000591111; = p.P7020S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2O | c.1301A>G p.E434G | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF239 | c.72A>T p.E24D | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF439 | c.164del p.L55Rfs*4 | Frame Shift Del (DEL) | VAF 38/212 reads (18%) | called by mutect2, varscan2
- ZNF638 | c.2111A>T p.N704I | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CSMD2 | c.1182C>T p.S394= | Silent (SNP) | VAF 38/221 reads (17%) | catalogued as rs746022676; called by muse, mutect2, varscan2
- CSPG4 | c.4419C>A p.P1473= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs201459470; called by muse, mutect2, varscan2
- DDX58 | c.642A>G p.Q214= | Silent (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- EYA1 | c.903G>A p.G301= | Silent (SNP) | VAF 16/582 reads (3%) | catalogued as rs1349506244, COSV58171383; called by muse, mutect2
- GRIP1 | c.2796G>T p.G932= (on ENST00000359742 / NM_001379345.1; = p.G880= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 49/258 reads (19%) | called by muse, mutect2, varscan2
- HECTD4 | c.10833G>A p.L3611= | Silent (SNP) | VAF 46/204 reads (23%) | catalogued as rs746648698; called by muse, mutect2, varscan2
- MYH9 | c.270G>A p.T90= | Silent (SNP) | VAF 58/236 reads (25%) | catalogued as rs780422191; called by muse, varscan2
- NINJ2 | c.417G>A p.R139= | Silent (SNP) | VAF 14/76 reads (18%) | called by mutect2, varscan2
- NOTCH1 | c.7587C>G p.V2529= | Silent (SNP) | VAF 46/217 reads (21%) | catalogued as COSV53040192; called by muse, mutect2, varscan2
- PCCA | c.1434T>A p.V478= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as COSV100886602; called by muse, mutect2, varscan2
- PCGF1 | c.420G>C p.G140= | Silent (SNP) | VAF 44/170 reads (26%) | called by muse, mutect2, varscan2
- PIGQ | c.990T>A p.A330= | Silent (SNP) | VAF 43/220 reads (20%) | called by muse, mutect2, varscan2
- RACK1 | c.6T>A p.T2= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV100958724; called by muse, mutect2
- SPEG | c.8646G>T p.P2882= | Silent (SNP) | VAF 56/293 reads (19%) | catalogued as rs755097485; called by muse, mutect2, varscan2
- STARD5 | c.90C>T p.C30= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs781744902, COSV100250792, COSV57154964; called by muse, mutect2, varscan2
- TOGARAM1 | c.864C>A p.G288= | Silent (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- WDFY4 | c.2328C>T p.G776= | Silent (SNP) | VAF 35/207 reads (17%) | catalogued as rs556802159; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3078G>T | Intron (SNP) | VAF 32/193 reads (17%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.1402+209C>T | Intron (SNP) | VAF 13/131 reads (10%) | catalogued as rs1483630149; called by muse, mutect2
- CCNB1IP1 | c.297+405A>G | Intron (SNP) | VAF 25/130 reads (19%) | catalogued as rs1290861234; called by muse, mutect2, varscan2
- DNAH10 | c.9645-798T>C | Intron (SNP) | VAF 82/476 reads (17%) | called by muse, mutect2, varscan2
- NLRX1 | c.*492del | 3'UTR (DEL) | VAF 23/137 reads (17%) | called by mutect2, pindel, varscan2
- TCTEX1D1 | c.211+140T>C | Intron (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- USP2-AS1 | n.225T>G | RNA (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
